Somatic mutation profile of tumor specimen TCGA-UF-A71D-01A (aliquot TCGA-UF-A71D-01A-12D-A34J-08) from TCGA case TCGA-UF-A71D, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 54.1 years (19,747 days).
Specimen TCGA-UF-A71D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16d158a3-778b-40ba-a34e-4069048e542b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A71D-10B (Blood Derived Normal), aliquot TCGA-UF-A71D-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1036c8c0-70d9-4e41-a7b0-fded70a5eb02

The open-access MAF lists 504 somatic variants for this specimen: 359 protein-altering or splice-affecting, 136 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 292, Silent 136, Nonsense Mutation 35, Splice Site 11, Frame Shift Del 11, Frame Shift Ins 6, RNA 4, Splice Region 3, Intron 3, 5'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 16/65 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.3484A>T p.K1162* | Nonsense Mutation (SNP) | VAF 25/87 reads (29%) | catalogued as COSV100588885; called by muse, mutect2, varscan2
- AAK1 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101276020; called by muse, mutect2, varscan2
- ABL2 | c.1001C>A p.A334E (on ENST00000502732 / NM_007314.4; = p.A319E on NM_005158.5) | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as COSV100772912; called by muse, mutect2, varscan2
- AC004593.2 | c.799A>G p.K267E | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.673); catalogued as COSV99765714; called by muse, mutect2, varscan2
- AC100868.1 | c.854T>A p.L285H | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99226622; called by muse, mutect2, varscan2
- ACACB | c.2155G>T p.V719L | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV100623166; called by muse, mutect2, varscan2
- ADAM19 | c.712A>G p.I238V | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV99978037; called by muse, mutect2, varscan2
- ADAMTS12 | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.867); catalogued as COSV61279213; called by muse, mutect2, varscan2
- ADAMTS5 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); catalogued as COSV99538143; called by muse, mutect2, varscan2
- ADCY1 | c.2947C>T p.P983S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99812666; called by muse, mutect2, varscan2
- ADGRL3 | c.2839G>T p.V947L (on ENST00000506720 / NM_001322402.2; = p.V879L on NM_015236.6) | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); catalogued as COSV72231244, COSV72231859, COSV72232087; called by muse, mutect2, varscan2
- AHNAK | c.13165G>A p.D4389N | Missense Mutation (SNP) | VAF 66/534 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99948915; called by muse, mutect2, varscan2
- AJUBA | c.1240-1G>C p.X414_splice | Splice Site (SNP) | VAF 25/62 reads (40%) | catalogued as COSV52984762, COSV99401134; called by muse, mutect2, varscan2
- AKAP6 | c.2997C>A p.Y999* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV99803259; called by muse, mutect2, varscan2
- AKAP8L | c.1011G>T p.E337D | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.024); catalogued as COSV101275845; called by muse, mutect2, varscan2
- AKAP9 | c.5566C>T p.R1856* (on ENST00000359028; = p.R1824* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as rs1371453011, COSV100662831; called by muse, mutect2, varscan2
- ALDH1L2 | c.1643T>C p.V548A | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV99311240; called by muse, mutect2, varscan2
- ANO5 | c.1282C>G p.P428A | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100202082; called by muse, mutect2
- APH1A | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV52530528, COSV99354482; called by muse, mutect2
- ARHGAP11A | c.2569G>C p.G857R | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100276896, COSV100276980; called by muse, mutect2, varscan2
- ASIC5 | c.585+1G>A p.X195_splice | Splice Site (SNP) | VAF 16/97 reads (16%) | catalogued as COSV101539784; called by muse, mutect2, varscan2
- ASS1 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100752781; called by muse, mutect2, varscan2
- ASTN2 | c.3681G>T p.E1227D (on ENST00000313400 / NM_001365069.1; = p.E1176D on NM_014010.5) | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.97); catalogued as rs1177740339, COSV99941290; called by muse, mutect2, varscan2
- ATP1A2 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as COSV100768080; called by muse, mutect2, varscan2
- AUTS2 | c.3062C>T p.S1021L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV61405006; called by muse, mutect2, varscan2
- BEST3 | c.489G>T p.M163I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV99876330; called by muse, mutect2, varscan2
- BRINP2 | c.1496T>A p.L499Q | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); catalogued as COSV100838260; called by muse, mutect2, varscan2
- BRSK1 | c.526G>T p.G176C | Missense Mutation (SNP) | VAF 92/226 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100510806; called by muse, mutect2, varscan2
- C10orf88 | c.749A>G p.N250S | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100925038; called by muse, mutect2, varscan2
- C11orf53 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as rs1304048875, COSV99724869; called by muse, mutect2, varscan2
- C1orf198 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV64176135; called by muse, mutect2, varscan2
- C2CD5 | c.1249T>G p.S417A | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.444); catalogued as COSV100448405, COSV100448947; called by muse, mutect2, varscan2
- C8B | c.1373A>G p.Y458C | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756205318, COSV100980860; called by muse, mutect2, varscan2
- CAMK1 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV99844888; called by muse, mutect2, varscan2
- CARD6 | c.2476G>T p.V826L | Missense Mutation (SNP) | VAF 148/696 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV99621121; called by muse, mutect2, varscan2
- CASC3 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99229945; called by muse, mutect2, varscan2
- CCDC85A | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.031); catalogued as rs372992628, COSV101339564; called by muse, mutect2, varscan2
- CCKAR | c.1163G>A p.C388Y | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769497506, COSV99810452; called by muse, mutect2, varscan2
- CCR6 | c.659T>A p.L220H | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.886); catalogued as COSV100551173, COSV59475015; called by muse, mutect2, varscan2
- CD244 | c.449G>T p.R150I (on ENST00000368033 / NM_001166663.2; = p.R145I on NM_016382.4) | Missense Mutation (SNP) | VAF 41/180 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV100458753; called by muse, mutect2, varscan2
- CDH18 | c.2117C>T p.T706I | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs368650801, COSV56955125; called by muse, mutect2, varscan2
- CDH9 | c.2114C>T p.P705L | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as rs1229333530, COSV99151103; called by muse, mutect2
- CDH9 | c.934G>A p.G312S | Missense Mutation (SNP) | VAF 44/316 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.28); catalogued as COSV99151104, COSV99163157; called by muse, mutect2, varscan2
- CDKAL1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV99216185; called by muse, mutect2
- CEMIP2 | c.3378G>A p.G1126= | Splice Region (SNP) | VAF 21/116 reads (18%) | catalogued as COSV100987475; called by muse, mutect2, varscan2
- CLK2 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | catalogued as COSV100751907; called by muse, mutect2
- CMIP | c.1552G>T p.V518L (on ENST00000537098 / NM_198390.2; = p.V424L on NM_030629.3) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as COSV104432631, COSV67700867; called by muse, mutect2, varscan2
- CNNM4 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 78/335 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100998779; called by muse, mutect2, varscan2
- CNTN3 | c.186G>A p.W62* | Nonsense Mutation (SNP) | VAF 27/98 reads (28%) | catalogued as COSV99725678; called by muse, mutect2, varscan2
- CNTNAP5 | c.3513C>G p.N1171K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101443912; called by muse, mutect2, varscan2
- COBL | c.3261C>G p.S1087R | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99473644; called by muse, mutect2, varscan2
- COBL | c.471G>T p.L157F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99473650; called by muse, mutect2, varscan2
- COG5 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99772828; called by muse, mutect2, varscan2
- COL11A1 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100617780; called by muse, mutect2
- COL16A1 | c.4603G>T p.G1535C | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54708166, COSV99595160; called by muse, mutect2, varscan2
- COL1A2 | c.842C>G p.P281R | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as COSV99800582, COSV99800638; called by muse, mutect2, varscan2
- COL5A3 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1292025969, COSV99319486; called by muse, mutect2, varscan2
- COL8A2 | c.988G>C p.A330P | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV100291312; called by muse, mutect2, varscan2
- CRACD | c.355-1G>T p.X119_splice | Splice Site (SNP) | VAF 113/356 reads (32%) | catalogued as COSV99949811; called by muse, mutect2, varscan2
- CRAT | c.1329G>A p.R443= | Splice Region (SNP) | VAF 43/195 reads (22%) | catalogued as COSV100540100; called by muse, mutect2, varscan2
- CRNKL1 | c.780G>A p.R260= | Splice Region (SNP) | VAF 15/51 reads (29%) | catalogued as COSV99846087; called by muse, mutect2, varscan2
- CRTC2 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100135653; called by mutect2, varscan2
- CSMD3 | c.10213G>A p.E3405K (on ENST00000297405 / NM_001363185.1; = p.E3236K on NM_052900.3) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as COSV52164185; called by muse, mutect2, varscan2
- CSMD3 | c.2606G>T p.G869V (on ENST00000297405 / NM_001363185.1; = p.G765V on NM_052900.3) | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52185822, COSV99826995; called by muse, mutect2, varscan2
- CTTN | c.1594G>T p.G532W | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100096885, COSV100098187; called by muse, mutect2
- CUL1 | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 51/242 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100296863; called by muse, mutect2, varscan2
- CYB5R3 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs752979917, COSV100677973, COSV61545674; called by muse, mutect2, varscan2
- CYLC1 | c.338C>A p.A113E | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.764); catalogued as COSV100255139; called by muse, mutect2, varscan2
- CYP26C1 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99606093; called by muse, varscan2
- DAXX | c.1986G>T p.K662N | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1453165364, COSV99802485; called by muse, mutect2, varscan2
- DBH | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV99708106; called by muse, mutect2, varscan2
- DCAF15 | c.593A>G p.D198G | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as COSV99586908; called by muse, mutect2, varscan2
- DCK | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99709270; called by muse, mutect2, varscan2
- DENND1A | c.1292A>T p.Y431F | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV101010761; called by muse, mutect2, varscan2
- DIO2 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV101375941; called by muse, mutect2
- DLGAP4 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV100211505; called by muse, mutect2, varscan2
- DMD | c.6235T>A p.S2079T | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100821902; called by muse, mutect2, varscan2
- DNAH5 | c.2235C>G p.Y745* | Nonsense Mutation (SNP) | VAF 28/133 reads (21%) | catalogued as COSV99452615; called by muse, mutect2, varscan2
- DNAH7 | c.11305G>A p.A3769T | Missense Mutation (SNP) | VAF 59/302 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.458); catalogued as COSV100416754; called by muse, mutect2, varscan2
- DNAH9 | c.5968T>C p.F1990L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99307335; called by muse, mutect2, varscan2
- DOK4 | c.156C>A p.C52* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99538426; called by muse, mutect2, varscan2
- DPP6 | c.786C>G p.I262M (on ENST00000377770 / NM_001364500.2; = p.I200M on NM_001936.5) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100127301; called by muse, mutect2, varscan2
- DSPP | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.237); catalogued as COSV99217776; called by muse, mutect2, varscan2
- DYNC2H1 | c.3853C>T p.Q1285* | Nonsense Mutation (SNP) | VAF 24/148 reads (16%) | catalogued as COSV100519395; called by muse, mutect2, varscan2
- DYNC2I1 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs771932685, COSV68104628; called by muse, mutect2, varscan2
- EPB41L3 | c.2359T>C p.S787P | Missense Mutation (SNP) | VAF 97/560 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV100549939; called by muse, mutect2, varscan2
- EPB41L4A | c.1907G>T p.G636V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV99813858; called by muse, mutect2, varscan2
- EYS | c.1001G>T p.S334I | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100676977; called by muse, varscan2
- EYS | c.341G>T p.C114F | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV100675702, COSV100676978; called by muse, mutect2, varscan2
- F10 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM082618, COSV100979284; called by muse, mutect2, varscan2
- FAM135B | c.1282A>T p.N428Y | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV99426316; called by muse, mutect2, varscan2
- FAM135B | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99424670; called by muse, mutect2, varscan2
- FAM155A | c.545T>A p.F182Y | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV101029638; called by muse, mutect2, varscan2
- FAM24A | c.163C>G p.H55D | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1244504448, COSV100925089; called by muse, mutect2, varscan2
- FAM91A1 | c.1861G>C p.D621H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV100593731; called by muse, mutect2, varscan2
- FAT1 | c.1982T>G p.I661R | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV101499566; called by muse, mutect2, varscan2
- FBXL6 | c.516G>T p.K172N | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV100095979; called by muse, mutect2
- FCGR3A | c.741G>C p.W247C | Missense Mutation (SNP) | VAF 22/357 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100914692; called by muse, mutect2
- FIGN | c.267C>G p.S89R | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV100292766; called by muse, mutect2, varscan2
- FLG | c.8936G>C p.G2979A | Missense Mutation (SNP) | VAF 101/878 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.381); catalogued as rs765947651; called by muse, mutect2
- FMO3 | c.1537C>A p.H513N | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100882530, COSV63006734; called by muse, mutect2, varscan2
- FOXB2 | c.782C>G p.A261G | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs1437403589, COSV100942373; called by muse, mutect2, varscan2
- FOXG1 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV100487011; called by muse, mutect2, varscan2
- FOXN4 | c.1284del p.F428Lfs*11 | Frame Shift Del (DEL) | VAF 10/106 reads (9%) | catalogued as COSV54493854; called by mutect2, pindel
- FRMPD1 | c.2380G>T p.E794* | Nonsense Mutation (SNP) | VAF 56/446 reads (13%) | catalogued as COSV100899607, COSV66703545; called by muse, mutect2, varscan2
- FSCB | c.2251G>T p.A751S | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.346); catalogued as COSV100469684, COSV61219814; called by muse, mutect2, varscan2
- FSIP2 | c.18280C>A p.P6094T | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.74); catalogued as COSV100555934; called by muse, mutect2, varscan2
- FSTL5 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 23/100 reads (23%) | catalogued as COSV100059451, COSV60185671; called by muse, mutect2, varscan2
- FZD10 | c.215C>G p.A72G | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.593); catalogued as COSV99969555; called by muse, mutect2
- GC | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.025); catalogued as COSV99910027; called by muse, mutect2, varscan2
- GLB1L2 | c.1108+1G>A p.X370_splice | Splice Site (SNP) | VAF 34/133 reads (26%) | catalogued as COSV100335451; called by muse, mutect2, varscan2
- GNA15 | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99505345; called by mutect2, varscan2
- GOLGB1 | c.4185T>A p.D1395E | Missense Mutation (SNP) | VAF 113/290 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100511359; called by muse, mutect2, varscan2
- GRIA4 | c.1501C>G p.L501V | Missense Mutation (SNP) | VAF 100/241 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99233661; called by muse, mutect2, varscan2
- GRID1 | c.2421C>A p.H807Q | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100025749; called by muse, mutect2, varscan2
- GRM1 | c.1673A>G p.D558G | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99268240; called by muse, mutect2, varscan2
- GRM1 | c.2009T>A p.M670K | Missense Mutation (SNP) | VAF 70/291 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV99268242; called by muse, mutect2, varscan2
- GRM7 | c.215G>C p.R72T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100737811, COSV63129731; called by muse, mutect2, varscan2
- GRM8 | c.1696C>A p.R566S | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.241); catalogued as COSV58840197; called by muse, mutect2, varscan2
- GULP1 | c.388A>T p.S130C | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100771029; called by muse, mutect2, varscan2
- GXYLT2 | c.811A>T p.M271L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV101274657; called by muse, mutect2, varscan2
- H2AC11 | c.82G>T p.V28L | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.2); catalogued as COSV100345857; called by muse, mutect2, varscan2
- H2AC14 | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100297664; called by muse, mutect2, varscan2
- HAO1 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101113282; called by muse, mutect2, varscan2
- HAO1 | c.850G>T p.G284W | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101113284; called by muse, mutect2, varscan2
- HDAC9 | c.1970A>G p.H657R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101286931; called by muse, mutect2, varscan2
- HK1 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1363984577, COSV100067556, COSV53865611; called by muse, mutect2, varscan2
- HNRNPUL2 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.204); catalogued as COSV57133390; called by muse, mutect2, varscan2
- HPCAL1 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57145988; called by muse, mutect2, varscan2
- HTR4 | c.1116C>A p.C372* | Nonsense Mutation (SNP) | VAF 37/122 reads (30%) | catalogued as COSV100089222; called by muse, mutect2, varscan2
- HYDIN | c.9812G>T p.G3271V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV101158020; called by muse, mutect2
- IDO1 | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs760377982, COSV99503555; called by muse, mutect2, varscan2
- IFI44 | c.1225G>C p.A409P | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV100877385, COSV66075336; called by muse, mutect2, varscan2
- IGHV1-18 | c.347C>A p.A116E | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs370195764; called by muse, mutect2
- IGLL1 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV99968657; called by muse, mutect2, varscan2
- IL16 | c.3002C>A p.S1001Y (on ENST00000302987 / NM_172217.5; = p.S300Y on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1416087555, COSV100267951; called by muse, mutect2, varscan2
- IL18R1 | c.1271-2A>T p.X424_splice | Splice Site (SNP) | VAF 28/62 reads (45%) | catalogued as COSV99295407; called by muse, mutect2, varscan2
- IMPA2 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 25/191 reads (13%) | catalogued as rs1282886289, COSV99302668; called by muse, mutect2, varscan2
- ING1 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs1229971429; called by muse, mutect2
- IQSEC1 | c.2530G>A p.A844T | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as COSV99832196; called by muse, mutect2, varscan2
- IRAK3 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99706352; called by muse, mutect2, varscan2
- IREB2 | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 12/134 reads (9%) | catalogued as COSV99359633; called by muse, mutect2
- ITGB8 | c.982C>G p.L328V | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV99752072; called by muse, mutect2, varscan2
- ITPR1 | c.2440G>A p.E814K (on ENST00000354582; = p.E799K on NM_002222.7) | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100228968; called by muse, mutect2, varscan2
- JARID2 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs767261258, COSV100522176; called by muse, mutect2, varscan2
- KBTBD8 | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV55127829, COSV99805835; called by muse, mutect2, varscan2
- KCNJ14 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as rs557935092, COSV100655800; called by muse, mutect2, varscan2
- KCNJ6 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757192158, COSV55711129, COSV99900269; called by muse, mutect2, varscan2
- KCTD16 | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV101568856; called by muse, mutect2, varscan2
- KIF18A | c.2395C>T p.R799W | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs193161481, COSV54180754; called by muse, mutect2
- KIF20A | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV50150493, COSV99137353; called by muse, mutect2, varscan2
- KLHDC8B | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as COSV100234288; called by muse, mutect2, varscan2
- KLHL4 | c.2090G>A p.W697* | Nonsense Mutation (SNP) | VAF 23/63 reads (37%) | catalogued as COSV64140481; called by muse, mutect2, varscan2
- KLKB1 | c.1168C>A p.R390S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52995448, COSV99250311; called by muse, mutect2, varscan2
- KMT2C | c.11567G>A p.R3856K | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.599); catalogued as COSV100075110; called by muse, mutect2, varscan2
- KPRP | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as COSV100908766, COSV100908826; called by muse, mutect2, varscan2
- KRT36 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV100057684; called by muse, mutect2, varscan2
- KRT78 | c.1181G>T p.C394F | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV100467528; called by muse, mutect2, varscan2
- KRT9 | c.1044+2T>C p.X348_splice | Splice Site (SNP) | VAF 8/52 reads (15%) | catalogued as COSV99879317; called by muse, mutect2, varscan2
- KRTAP1-3 | c.243C>A p.C81* | Nonsense Mutation (SNP) | VAF 34/90 reads (38%) | catalogued as COSV100727484, COSV60335637; called by muse, mutect2, varscan2
- LAMA1 | c.3446C>G p.P1149R | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.532); catalogued as COSV101057303; called by muse, mutect2, varscan2
- LAMA1 | c.3445C>G p.P1149A | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as rs752008334, COSV101057307; called by muse, mutect2, varscan2
- LAMA2 | c.2338A>T p.T780S | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101370727; called by muse, mutect2, varscan2
- LAMA3 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100557453; called by muse, mutect2, varscan2
- LDAH | c.725del p.G242Afs*4 | Frame Shift Del (DEL) | VAF 81/271 reads (30%) | catalogued as COSV52970011; called by mutect2, pindel, varscan2
- LIPA | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.063); catalogued as COSV99260830; called by muse, mutect2, varscan2
- LPXN | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 11/63 reads (17%) | catalogued as rs777112992, COSV101223105; called by muse, mutect2, varscan2
- LSAMP | c.122T>A p.I41N | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100372273; called by muse, mutect2, varscan2
- LYN | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV101319629; called by muse, mutect2, varscan2
- MAP3K19 | c.3247G>A p.G1083R | Missense Mutation (SNP) | VAF 71/243 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100209020; called by muse, mutect2, varscan2
- MAP3K19 | c.28C>G p.H10D | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100209024; called by muse, mutect2, varscan2
- MAP9 | c.1153A>G p.S385G | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100251046; called by muse, mutect2, varscan2
- MATR3 | c.1159A>G p.R387G | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.95); catalogued as COSV100735285; called by muse, mutect2, varscan2
- MDGA2 | c.1547C>T p.P516L (on ENST00000399232 / NM_001113498.2; = p.P218L on NM_182830.4) | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100637873; called by muse, mutect2, varscan2
- MFAP1 | c.1260G>C p.K420N | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as COSV99980040; called by muse, mutect2, varscan2
- MKI67 | c.7487T>G p.L2496R | Missense Mutation (SNP) | VAF 59/349 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV100896886; called by muse, mutect2, varscan2
- MMEL1 | c.2240+1G>A p.X747_splice | Splice Site (SNP) | VAF 11/145 reads (8%) | catalogued as COSV99984275; called by muse, mutect2
- MMP10 | c.348G>T p.R116S | Missense Mutation (SNP) | VAF 108/234 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99666712; called by muse, mutect2, varscan2
- MMP2 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV99528113; called by muse, mutect2
- MMUT | c.1389A>G p.I463M | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.113); catalogued as COSV51273986; called by muse, mutect2, varscan2
- MS4A1 | c.646T>A p.W216R | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61942678; called by muse, mutect2, varscan2
- MTARC1 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV100856340; called by muse, mutect2, varscan2
- MTBP | c.204T>G p.C68W | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100012453; called by muse, mutect2
- MTNR1B | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as CM121595, COSV99925260, COSV99925443; called by muse, mutect2, varscan2
- MTO1 | c.1832C>T p.A611V (on ENST00000370300 / NM_133645.3; = p.A586V on NM_012123.4) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100940504; called by muse, mutect2, varscan2
- MUC17 | c.4100C>A p.P1367H | Missense Mutation (SNP) | VAF 154/564 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); catalogued as COSV100074585; called by muse, mutect2, varscan2
- MUSK | c.1420G>T p.D474Y | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as COSV99504815; called by muse, mutect2, varscan2
- MVD | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772656834, COSV99880112; called by muse, mutect2, varscan2
- MYH2 | c.3650A>T p.Q1217L | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99818967; called by muse, mutect2, varscan2
- MYH8 | c.743G>A p.G248D | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101238614; called by muse, mutect2, varscan2
- NACA | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100771542, COSV100771750; called by muse, mutect2
- NALCN | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1566630752, COSV99216923; called by muse, mutect2, varscan2
- NAV1 | c.1993_1994insT p.R665Lfs*3 | Frame Shift Ins (INS) | VAF 33/197 reads (17%) | catalogued as COSV99819422; called by mutect2, pindel, varscan2
- NBAS | c.235G>T p.G79* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99871173; called by muse, mutect2, varscan2
- NEBL | c.1005T>A p.S335R | Missense Mutation (SNP) | VAF 98/167 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101009303; called by muse, mutect2, varscan2
- NEK8 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); catalogued as COSV99262180; called by muse, mutect2, varscan2
- NLRP5 | c.2771C>A p.A924D | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.326); catalogued as COSV101173830; called by muse, mutect2, varscan2
- NRXN1 | c.2560G>T p.E854* | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as COSV100456356, COSV58480987; called by muse, mutect2, varscan2
- NSD1 | c.2765del p.T922Rfs*6 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as COSV100729913; called by mutect2, pindel*, varscan2
- NSUN5 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.419); catalogued as rs1554541970, COSV99392507; called by muse, mutect2, varscan2
- NXPH2 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV55646116, COSV99741125; called by muse, mutect2
- OPRK1 | c.635T>A p.L212* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV99654289; called by muse, mutect2, varscan2
- OR10AD1 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100046905, COSV100046935; called by muse, mutect2, varscan2
- OR11L1 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100869470; called by muse, mutect2, varscan2
- OR1A2 | c.713G>C p.C238S | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101126377; called by muse, mutect2, varscan2
- OR2F2 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101283840, COSV68833146; called by muse, mutect2, varscan2
- OR2T33 | c.285T>G p.C95W | Missense Mutation (SNP) | VAF 58/434 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100532193, COSV58816109; called by muse, mutect2
- OR6C4 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV101263166; called by muse, mutect2, varscan2
- OR6K6 | c.310A>C p.T104P (on ENST00000368144; = p.T80P on NM_001005184.1) | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as COSV63744352; called by muse, mutect2, varscan2
- OR8B12 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.089); catalogued as rs141942599; called by muse, mutect2, varscan2
- OR8I2 | c.778C>A p.Q260K | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV100136218; called by muse, mutect2, varscan2
- P2RY6 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 53/277 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100573950, COSV62936285; called by muse, mutect2, varscan2
- PAPPA2 | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 48/317 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs369706751, COSV62779735; called by muse, mutect2, varscan2
- PCDH15 | c.3172A>G p.I1058V | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.196); catalogued as COSV100225564; called by muse, mutect2, varscan2
- PCDH15 | c.932G>C p.R311P | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100225566, COSV57377261; called by muse, mutect2, varscan2
- PCDHA1 | c.1354G>T p.A452S | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV100974422, COSV65373288; called by muse, mutect2, varscan2
- PCDHGA3 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.059); catalogued as COSV54039835; called by muse, mutect2, varscan2
- PCLO | c.9937C>T p.R3313W | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs758970673, COSV61617340; called by muse, mutect2, varscan2
- PCNX3 | c.3113C>T p.P1038L | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1255546243, COSV100856567; called by muse, mutect2, varscan2
- PDE3A | c.2686C>T p.H896Y | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100762661; called by muse, mutect2, varscan2
- PDE3A | c.3112G>A p.D1038N | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.238); catalogued as COSV100762662; called by muse, mutect2, varscan2
- PDE4B | c.1712C>T p.S571F | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100304530; called by muse, mutect2, varscan2
- PDE5A | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); catalogued as rs374654706, COSV99309037; called by muse, mutect2, varscan2
- PDZD2 | c.2857C>T p.R953* | Nonsense Mutation (SNP) | VAF 41/160 reads (26%) | catalogued as COSV99225919; called by muse, mutect2, varscan2
- PHF1 | c.965T>C p.I322T | Missense Mutation (SNP) | VAF 87/282 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV100992656; called by muse, mutect2, varscan2
- PIK3CG | c.847G>T p.G283C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100783063; called by muse, mutect2, varscan2
- PIM1 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as COSV100998747, COSV65164775; called by muse, mutect2, varscan2
- PIWIL1 | c.1488G>A p.W496* | Nonsense Mutation (SNP) | VAF 32/97 reads (33%) | catalogued as COSV99806772; called by muse, mutect2, varscan2
- PJA1 | c.1889G>A p.G630D (on ENST00000361478 / NM_145119.4; = p.G442D on NM_022368.5) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64053054, COSV64053786; called by muse, mutect2, varscan2
- PKHD1L1 | c.8369G>A p.W2790* | Nonsense Mutation (SNP) | VAF 41/93 reads (44%) | catalogued as COSV101006636; called by muse, mutect2, varscan2
- PLA1A | c.247G>T p.G83* | Nonsense Mutation (SNP) | VAF 35/202 reads (17%) | catalogued as COSV56333664; called by muse, mutect2, varscan2
- PLA2G7 | c.1153A>T p.N385Y | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99221549; called by muse, mutect2, varscan2
- PLCB2 | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV99542456; called by muse, mutect2, varscan2
- PLCL1 | c.2443C>A p.P815T | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101407238, COSV70820920; called by muse, mutect2, varscan2
- PLCZ1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV99855703; called by muse, mutect2, varscan2
- PLEKHH2 | c.1262A>T p.N421I | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99175000; called by muse, mutect2, varscan2
- PNLIPRP2 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100077903, COSV53946118; called by muse, mutect2, varscan2
- PPP1R9A | c.719C>A p.S240Y | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as COSV99196834; called by muse, mutect2, varscan2
- PREX1 | c.298T>A p.F100I | Missense Mutation (SNP) | VAF 62/347 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100906657; called by muse, mutect2, varscan2
- PRTG | c.1210A>G p.I404V | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101221460; called by muse, mutect2, varscan2
- PSD3 | c.2939G>T p.R980L (on ENST00000440756; = p.R979L on NM_015310.4) | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54072057, COSV99676557; called by muse, mutect2, varscan2
- PSD3 | c.2059C>G p.L687V | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54073537; called by muse, mutect2, varscan2
- PTCRA | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV100485810, COSV58975968; called by muse, mutect2
- PTX3 | c.636G>T p.W212C | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99904961; called by muse, mutect2, varscan2
- PXMP4 | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs200916380; called by muse, mutect2, varscan2
- RABAC1 | c.230A>G p.N77S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782781608, COSV99706089; called by muse, mutect2, varscan2
- RABGAP1L | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99273115; called by muse, mutect2, varscan2
- RAI14 | c.1400T>C p.V467A | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99464207; called by muse, mutect2, varscan2
- RBP3 | c.3157G>A p.G1053S | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs140160521; called by muse, mutect2, varscan2
- RNF17 | c.4783C>T p.P1595S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99694068; called by muse, mutect2, varscan2
- ROBO2 | c.587G>C p.S196T | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.272); catalogued as COSV100168996; called by muse, mutect2, varscan2
- ROCK2 | c.3005-2A>T p.X1002_splice | Splice Site (SNP) | VAF 29/137 reads (21%) | catalogued as COSV100255714; called by muse, mutect2, varscan2
- RRH | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV100496191; called by muse, mutect2, varscan2
- RTKN2 | c.753G>C p.K251N | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV100189562; called by muse, mutect2, varscan2
- RTL3 | c.10G>C p.D4H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.946); catalogued as COSV100330005; called by muse, mutect2
- RUNX1T1 | c.925C>A p.H309N (on ENST00000265814 / NM_001198628.1; = p.H282N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV99753973; called by muse, mutect2, varscan2
- RUSC2 | c.1858C>T p.Q620* | Nonsense Mutation (SNP) | VAF 10/154 reads (6%) | catalogued as COSV100770818; called by muse, mutect2
- RYR1 | c.14804G>A p.G4935D | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100616600; called by muse, mutect2, varscan2
- RYR3 | c.8197G>A p.G2733R (on ENST00000389232; = p.G2734R on NM_001036.6) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.132); catalogued as COSV66810648; called by muse, mutect2
- SBF1 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV100817962; called by muse, mutect2, varscan2
- SCN1A | c.2811C>A p.F937L (on ENST00000303395 / NM_001202435.3; = p.F926L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/234 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57665680; called by muse, mutect2, varscan2
- SCN2A | c.2918T>C p.V973A | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV99332902; called by muse, mutect2, varscan2
- SEMA6B | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100015047; called by muse, mutect2, varscan2
- SERPINA4 | c.1180C>G p.R394G | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs776919966, COSV100097379, COSV54068978; called by muse, mutect2, varscan2
- SH2D3C | c.1977G>T p.E659D (on ENST00000314830 / NM_170600.3; = p.E502D on NM_005489.4) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.423); catalogued as COSV100137286; called by muse, mutect2, varscan2
- SH3PXD2B | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100288372; called by muse, mutect2, varscan2
- SIPA1L1 | c.4373C>T p.P1458L | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV100665871; called by muse, mutect2
- SLC12A9 | c.163G>T p.V55F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99308072; called by muse, mutect2, varscan2
- SLC16A10 | c.1354T>C p.F452L | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100920947; called by muse, mutect2, varscan2
- SLC16A5 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100317207; called by muse, mutect2, varscan2
- SLC18A2 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs778930963, COSV100041934; called by muse, mutect2, varscan2
- SLC40A1 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99656462; called by muse, mutect2, varscan2
- SLC6A2 | c.1657T>A p.W553R | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99574369; called by muse, mutect2, varscan2
- SLC9C2 | c.1436A>C p.D479A | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV100876936; called by muse, mutect2, varscan2
- SMC2 | c.3357G>T p.L1119F | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99659468; called by muse, mutect2, varscan2
- SPAG6 | c.1363G>A p.G455S | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.356); catalogued as COSV100510420; called by muse, mutect2, varscan2
- SPATA31E1 | c.2096C>G p.S699C | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV100350851; called by muse, mutect2, varscan2
- SPEF2 | c.2926G>T p.G976* | Nonsense Mutation (SNP) | VAF 25/101 reads (25%) | catalogued as COSV61554067; called by muse, mutect2, varscan2
- SPTLC3 | c.646G>C p.A216P | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100983240; called by muse, mutect2, varscan2
- SREBF2 | c.2039G>T p.G680V | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100761520; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2461A>T p.I821F | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100562114; called by muse, mutect2, varscan2
- SUMF1 | c.1070C>G p.S357C | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1489482200, COSV99795026; called by muse, mutect2, varscan2
- SYCP2 | c.3628G>C p.E1210Q | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.525); catalogued as COSV100698391; called by muse, mutect2, varscan2
- SYK | c.1740A>T p.E580D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV101002580, COSV65325780; called by muse, mutect2
- SYNE1 | c.22266G>C p.L7422F (on ENST00000367255 / NM_182961.4; = p.L7351F on NM_033071.3) | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99574514; called by muse, mutect2, varscan2
- TBC1D4 | c.1205G>T p.C402F | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1172991301, COSV100884746; called by muse, mutect2, varscan2
- TENT4A | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV100049188; called by muse, mutect2, varscan2
- TEX47 | c.393T>G p.I131M | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99787353; called by muse, varscan2
- TFRC | c.435G>T p.K145N | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as COSV100786572; called by muse, varscan2
- TGM6 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374951502; called by muse, mutect2, varscan2
- THAP8 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV53077797; called by muse, mutect2
- TLE1 | c.1408G>T p.G470* | Nonsense Mutation (SNP) | VAF 54/169 reads (32%) | catalogued as COSV100918951, COSV64719657; called by muse, mutect2, varscan2
- TLL2 | c.2787C>A p.Y929* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | catalogued as rs973244513, COSV100780368, COSV100780407; called by muse, mutect2, varscan2
- TMC7 | c.2063C>G p.A688G | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV100432735; called by muse, varscan2
- TMED5 | c.396G>C p.Q132H | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as COSV100939190; called by muse, mutect2, varscan2
- TMEFF1 | c.386G>A p.C129Y | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614906; called by muse, mutect2, varscan2
- TMEM200B | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV100549237; called by muse, mutect2, varscan2
- TMEM200C | c.448G>C p.G150R | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101274857; called by muse, mutect2, varscan2
- TMEM88 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99642071; called by muse, mutect2, varscan2
- TMPRSS2 | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV100152053, COSV59826399; called by muse, mutect2, varscan2
- TNIK | c.1705G>C p.E569Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.942); catalogued as COSV52690971, COSV99458893; called by muse, mutect2, varscan2
- TNIP1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100161661; called by muse, mutect2, varscan2
- TNNI3K | c.2317C>A p.L773I | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.123); catalogued as COSV99632081; called by muse, mutect2, varscan2
- TNRC6B | c.4947G>C p.W1649C (on ENST00000454349 / NM_001162501.2; = p.W1539C on NM_015088.3) | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100110280; called by muse, mutect2, varscan2
- TOGARAM1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as rs1014816249, COSV100753221; called by muse, mutect2, varscan2
- TP53 | c.250del p.A84Pfs*39 | Frame Shift Del (DEL) | VAF 75/163 reads (46%) | catalogued as COSV53077353; called by mutect2, pindel, varscan2
- TPCN1 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100136961; called by muse, mutect2, varscan2
- TRIL | c.868A>C p.S290R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100538924; called by muse, mutect2, varscan2
- TRMT1 | c.1226G>A p.G409D | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.026); catalogued as rs1335116781, COSV99679188; called by muse, mutect2, varscan2
- TRPC5 | c.733T>C p.S245P | Missense Mutation (SNP) | VAF 104/233 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV99462223; called by muse, mutect2, varscan2
- TTC21A | c.3919A>T p.R1307W | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99827037; called by muse, mutect2, varscan2
- TULP4 | c.556A>C p.T186P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100893715; called by muse, mutect2, varscan2
- TYR | c.667C>A p.Q223K | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.303); catalogued as COSV54477352; called by muse, mutect2, varscan2
- USH2A | c.2502C>G p.F834L | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.192); catalogued as COSV100239917; called by muse, mutect2
- USP3 | c.1399G>A p.V467I | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV99165773; called by muse, mutect2, varscan2
- USP33 | c.2468G>A p.R823K | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.308); catalogued as rs1058816, COSV100657192; called by muse, mutect2, varscan2
- USP48 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57608875; called by muse, mutect2, varscan2
- USP53 | c.2098A>T p.N700Y | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV99917969; called by muse, mutect2, varscan2
- USP9X | c.7490A>G p.D2497G | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV100199910; called by muse, mutect2, varscan2
- UTP20 | c.5887G>T p.D1963Y | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs867034932, COSV99882240; called by muse, mutect2, varscan2
- VARS1 | c.3293C>T p.S1098F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.325); catalogued as COSV100791844; called by muse, mutect2, varscan2
- VCAM1 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV99658814; called by muse, mutect2, varscan2
- VPS13B | c.2693C>G p.P898R | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV100662991; called by muse, varscan2
- VWCE | c.2204C>A p.P735H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV100076063; called by muse, mutect2, varscan2
- WDR88 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV50112507, COSV99404245; called by muse, mutect2, varscan2
- WFIKKN2 | c.1534G>T p.D512Y | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100259742, COSV100260043; called by muse, mutect2, varscan2
- WNT8A | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); catalogued as COSV100843081; called by muse, mutect2, varscan2
- ZFHX4 | c.4943G>C p.G1648A | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV50636410, COSV51505776, COSV99266152; called by muse, mutect2, varscan2
- ZFHX4 | c.7467G>T p.Q2489H | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99266156; called by muse, mutect2
- ZHX1 | c.1361A>T p.K454I | Missense Mutation (SNP) | VAF 91/466 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as COSV99933815; called by muse, mutect2, varscan2
- ZIC1 | c.382T>A p.F128I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.827); catalogued as COSV99292245; called by mutect2, varscan2
- ZIC4 | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV101268096, COSV67171581; called by muse, mutect2, varscan2
- ZNF491 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV100022016; called by muse, mutect2, varscan2
- ZNF521 | c.640T>C p.S214P | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as COSV100833048; called by muse, mutect2, varscan2
- ZNF549 | c.1067C>T p.T356I (on ENST00000376233 / NM_001199295.2; = p.T343I on NM_153263.2) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV99558715; called by muse, mutect2, varscan2
- ZNF91 | c.2518G>A p.A840T | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV100323312; called by muse, mutect2, varscan2
- ZRANB1 | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.082); catalogued as COSV100669304; called by muse, mutect2, varscan2
- ANGPT1 | c.12C>G p.F4L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASXL3 | c.6071del p.P2024Lfs*56 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | called by mutect2, pindel, varscan2
- C12orf4 | c.362G>A p.W121* | Nonsense Mutation (SNP) | VAF 27/140 reads (19%) | called by muse, mutect2, varscan2
- CCL16 | c.67A>T p.S23C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCL8 | c.3del p.M1? | Frame Shift Del (DEL) | VAF 37/94 reads (39%) | called by mutect2, pindel, varscan2
- ELAVL1 | c.44dup p.D16* | Frame Shift Ins (INS) | VAF 34/184 reads (18%) | called by mutect2, pindel, varscan2
- FHOD1 | c.600_601del p.H200Qfs*2 | Frame Shift Del (DEL) | VAF 19/121 reads (16%) | called by pindel, varscan2
- HLA-B | c.895+1dup p.X299_splice | Splice Site (INS) | VAF 21/97 reads (22%) | called by mutect2, pindel, varscan2
- KIF24 | c.2739_2742del p.S913Rfs*31 | Frame Shift Del (DEL) | VAF 39/384 reads (10%) | called by mutect2, pindel
- MPC1 | c.104dup p.L36Sfs*8 | Frame Shift Ins (INS) | VAF 49/213 reads (23%) | called by mutect2, pindel, varscan2
- NFE2L2 | c.603dup p.I202Yfs*2 | Frame Shift Ins (INS) | VAF 33/125 reads (26%) | called by mutect2, pindel, varscan2
- NRCAM | c.2705dup p.I903Dfs*20 (on ENST00000379028 / NM_001371124.1; = p.I887Dfs*20 on NM_005010.4 and 21 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 21/77 reads (27%) | called by mutect2, pindel, varscan2
- OR2T27 | c.914T>A p.V305E | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2
- PHLDB1 | c.3858_3872del p.L1287_V1291del | In Frame Del (DEL) | VAF 41/151 reads (27%) | called by mutect2, pindel, varscan2
- PPFIA4 | c.1586del p.P529Qfs*10 (on ENST00000447715; = p.P504Qfs*10 on NM_001304331.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/61 reads (10%) | called by mutect2, pindel
- PSME4 | c.759+1del p.X253_splice | Splice Site (DEL) | VAF 63/214 reads (29%) | called by mutect2, pindel, varscan2
- SOX2 | c.730del p.V244Sfs*30 | Frame Shift Del (DEL) | VAF 15/103 reads (15%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.3040G>T p.E1014* | Nonsense Mutation (SNP) | VAF 48/427 reads (11%) | called by muse, mutect2, varscan2
- STARD13 | c.872dup p.L291Ffs*9 (on ENST00000336934 / NM_001243476.3; = p.L173Ffs*9 on NM_052851.3) | Frame Shift Ins (INS) | VAF 26/83 reads (31%) | called by mutect2, pindel, varscan2
- WT1 | c.965+1del p.X322_splice | Splice Site (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- ZBBX | c.1133del p.P378Qfs*2 | Frame Shift Del (DEL) | VAF 22/162 reads (14%) | called by mutect2, pindel, varscan2
- ABCC1 | c.3576C>T p.S1192= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV100580105; called by muse, mutect2, varscan2
- ADM | c.60C>T p.D20= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99534337; called by muse, mutect2, varscan2
- AGBL1 | c.855G>T p.P285= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV101408171; called by muse, mutect2, varscan2
- AKAP9 | c.10797G>A p.V3599= (on ENST00000359028; = p.V3575= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/237 reads (24%) | catalogued as rs773824859, COSV100662833; called by muse, mutect2, varscan2
- AL021546.1 | c.105C>T p.Y35= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV99984897; called by muse, mutect2, varscan2
- ANKEF1 | c.1584G>T p.P528= | Silent (SNP) | VAF 43/130 reads (33%) | catalogued as COSV101001057; called by muse, mutect2, varscan2
- ANO8 | c.2748C>T p.H916= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs1430190281, COSV99344808; called by muse, mutect2, varscan2
- AP002512.3 | c.675G>A p.R225= | Silent (SNP) | VAF 36/181 reads (20%) | catalogued as COSV99688082; called by muse, mutect2, varscan2
- AP2B1 | c.1566G>C p.R522= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as COSV99251518; called by muse, mutect2, varscan2
- APRT | c.228C>T p.A76= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1336446072, COSV51940461; called by muse, mutect2, varscan2
- ARHGEF37 | c.63G>A p.R21= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV100382275; called by muse, mutect2, varscan2
- ARHGEF40 | c.42C>T p.L14= | Silent (SNP) | VAF 7/89 reads (8%) | catalogued as rs1200596269, COSV100070587; called by muse, mutect2
- ATF3 | c.186G>T p.L62= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as COSV100422086; called by muse, mutect2, varscan2
- ATP6V1G3 | c.192C>T p.G64= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as COSV55279476; called by muse, mutect2, varscan2
- BANP | c.747G>A p.E249= (on ENST00000286122; = p.E218= on NM_017869.4) | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV99622059; called by muse, mutect2, varscan2
- BEND5 | c.750C>T p.P250= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs148772068, COSV100884158; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3297G>A p.S1099= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs777448812, COSV63247150; called by muse, mutect2, varscan2
- CA12 | c.882C>G p.V294= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV99458606; called by muse, mutect2, varscan2
- CA2 | c.486G>A p.V162= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as rs763576424, COSV99570208; called by muse, mutect2, varscan2
- CACNA1E | c.4674C>A p.I1558= | Silent (SNP) | VAF 32/60 reads (53%) | catalogued as COSV100704495; called by muse, varscan2
- CACNG3 | c.882C>T p.S294= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV99136899; called by muse, mutect2, varscan2
- CCSER1 | c.492C>T p.F164= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100394974; called by muse, mutect2, varscan2
- CDC16 | c.354C>A p.S118= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99373086; called by muse, mutect2, varscan2
- CDH6 | c.1704G>T p.V568= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as COSV99420295; called by muse, mutect2, varscan2
- CNTNAP3 | c.2823C>A p.A941= | Silent (SNP) | VAF 24/202 reads (12%) | catalogued as COSV99905423; called by muse, varscan2
- CNTNAP4 | c.2094G>A p.L698= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as COSV100272691, COSV56668427; called by muse, mutect2, varscan2
- COBL | c.1806C>A p.P602= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV99473645; called by muse, mutect2, varscan2
- COL11A1 | c.4209G>A p.K1403= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs760416069, COSV100617778; called by muse, mutect2, varscan2
- CYLC1 | c.339A>C p.A113= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV100255146; called by muse, mutect2, varscan2
- DAGLB | c.426C>T p.I142= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV99766068; called by muse, mutect2, varscan2
- DIRAS2 | c.591G>T p.V197= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV101005892; called by muse, varscan2
- DNAH7 | c.3921G>T p.T1307= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV100416756; called by muse, mutect2, varscan2
- DPP9 | c.1629G>C p.T543= (on ENST00000598800; = p.T572= on NM_139159.5) | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99506403; called by muse, varscan2
- EAF1 | c.705C>T p.A235= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as rs367835501; called by muse, mutect2, varscan2
- EMILIN2 | c.1605C>A p.V535= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV99598781; called by muse, mutect2, varscan2
- ETV1 | c.1362T>C p.D454= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs773216548, COSV99624253; called by muse, mutect2, varscan2
- F8 | c.1131C>T p.V377= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV100811748; called by muse, mutect2, varscan2
- FAM71E1 | c.267C>A p.P89= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100618528; called by muse, mutect2
- FAT3 | c.8295T>C p.I2765= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV99969034; called by muse, mutect2, varscan2
- FGF5 | c.402A>G p.R134= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV100428013; called by muse, mutect2, varscan2
- FLNB | c.573G>C p.P191= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV55874856, COSV55881977; called by muse, mutect2, varscan2
- FNDC1 | c.3879C>A p.T1293= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV99796403; called by muse, mutect2
- FRG2C | c.477G>C p.R159= | Silent (SNP) | VAF 42/257 reads (16%) | called by mutect2, varscan2
- FRYL | c.4047C>T p.R1349= | Silent (SNP) | VAF 50/201 reads (25%) | catalogued as rs1428231056, COSV99977721; called by muse, mutect2, varscan2
- FSCB | c.2250G>A p.E750= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as rs1355860844, COSV100469686; called by muse, mutect2, varscan2
- GABRG3 | c.945C>A p.A315= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV100409136; called by muse, mutect2, varscan2
- GALNT9 | c.1695C>A p.G565= (on ENST00000328957 / NM_001122636.2; = p.G199= on NM_021808.3) | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV100201977; called by muse, mutect2, varscan2
- GPATCH2 | c.546C>T p.T182= | Silent (SNP) | VAF 48/222 reads (22%) | catalogued as rs1224329374, COSV100861415; called by muse, varscan2
- GRB14 | c.555A>G p.L185= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as COSV99814322; called by muse, mutect2, varscan2
- GRM5 | c.519A>T p.S173= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as COSV100553634; called by muse, mutect2
- GSTA5 | c.216T>C p.L72= | Silent (SNP) | VAF 77/319 reads (24%) | catalogued as rs745547782, COSV52861804; called by muse, mutect2, varscan2
- H4C11 | c.219T>C p.Y73= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs751184309, COSV100748006; called by muse, mutect2, varscan2
- HERC2 | c.5382C>T p.T1794= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99875922; called by muse, mutect2, varscan2
- HK3 | c.2277C>T p.I759= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as rs369639684; called by muse, mutect2, varscan2
- HNRNPU | c.1218A>G p.G406= (on ENST00000283179; = p.G468= on NM_004501.3) | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV99310579; called by muse, mutect2, varscan2
- HORMAD1 | c.621T>A p.P207= | Silent (SNP) | VAF 100/200 reads (50%) | catalogued as COSV100464349; called by muse, mutect2, varscan2
- HSPH1 | c.1323G>A p.E441= | Silent (SNP) | VAF 19/209 reads (9%) | catalogued as COSV100185085; called by muse, mutect2
- IL16 | c.2665C>A p.R889= (on ENST00000302987 / NM_172217.5; = p.R188= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV100267492, COSV100267948; called by muse, mutect2, varscan2
- IL17RA | c.345T>A p.S115= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV100083379; called by muse, mutect2, varscan2
- IL18R1 | c.903C>T p.A301= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as rs1051558618, COSV99295404; called by muse, mutect2, varscan2
- IL1RAPL2 | c.258C>A p.P86= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV100781770; called by muse, mutect2, varscan2
- KCNB2 | c.867C>T p.S289= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as rs764537038, COSV101578919; called by muse, mutect2, varscan2
- KDM2B | c.2925G>A p.S975= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100997566; called by muse, mutect2, varscan2
- KIAA1328 | c.999A>G p.E333= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV99695019; called by muse, mutect2
- KIAA1755 | c.2019G>A p.A673= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as rs1293777237, COSV54079373, COSV99642511; called by muse, mutect2
- KRT33B | c.558G>A p.E186= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV52442103, COSV99290761; called by muse, mutect2
- KRT7 | c.420C>T p.I140= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100081734; called by muse, mutect2, varscan2
- KRTAP19-3 | c.99C>G p.R33= | Silent (SNP) | VAF 102/342 reads (30%) | catalogued as COSV100477622; called by muse, mutect2, varscan2
- LCP2 | c.1590A>T p.A530= | Silent (SNP) | VAF 84/189 reads (44%) | catalogued as COSV99253316; called by muse, mutect2, varscan2
- LGALS9B | c.57G>A p.G19= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as COSV100163021; called by muse, mutect2, varscan2
- LIPE | c.1341G>A p.E447= | Silent (SNP) | VAF 26/40 reads (65%) | catalogued as COSV99734331; called by muse, mutect2, varscan2
- LRRC14B | c.744C>T p.T248= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99360849; called by muse, mutect2
- MAP3K12 | c.1698G>A p.V566= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs967246115, COSV99913462; called by muse, mutect2, varscan2
- MICALL1 | c.1932C>T p.S644= | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as rs1488176330, COSV99317496; called by muse, mutect2
- MMP13 | c.1188G>C p.L396= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as COSV99506760; called by muse, mutect2, varscan2
- MROH2B | c.2007A>G p.L669= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV101270858; called by muse, mutect2, varscan2
- MSTO1 | c.330C>T p.P110= | Silent (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- MYH4 | c.5724G>A p.E1908= | Silent (SNP) | VAF 59/241 reads (24%) | catalogued as rs1054593429, COSV99701932; called by muse, mutect2, varscan2
- MYO16 | c.969C>A p.T323= | Silent (SNP) | VAF 46/150 reads (31%) | catalogued as COSV51791213, COSV99194342; called by muse, mutect2, varscan2
- MYO7B | c.690G>C p.A230= | Silent (SNP) | VAF 30/153 reads (20%) | catalogued as COSV101268341, COSV67353037; called by muse, mutect2, varscan2
- NAT16 | c.948C>T p.H316= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100296356; called by muse, mutect2, varscan2
- NCAM2 | c.409C>A p.R137= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV53054950, COSV99524564; called by muse, mutect2, varscan2
- NFRKB | c.3870G>A p.P1290= (on ENST00000446488 / NM_001143835.2; = p.P1315= on NM_006165.3) | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as rs960556226, COSV99859507; called by muse, mutect2, varscan2
- NLGN1 | c.1062A>T p.I354= | Silent (SNP) | VAF 91/297 reads (31%) | catalogued as COSV100849836; called by muse, mutect2, varscan2
- NLGN4X | c.2361G>A p.T787= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs374449420, COSV99323338; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NXPE1 | c.918A>G p.T306= (on ENST00000424269; = p.T164= on NM_152315.5) | Silent (SNP) | VAF 19/122 reads (16%) | catalogued as rs1241371120, COSV99320819; called by muse, mutect2, varscan2
- OPRD1 | c.804C>T p.G268= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV52381700; called by muse, mutect2, varscan2
- OR13C9 | c.510G>A p.R170= | Silent (SNP) | VAF 41/153 reads (27%) | catalogued as COSV52243199; called by muse, mutect2, varscan2
- OR9G4 | c.552G>A p.L184= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs992888582, COSV100265015, COSV100265223; called by muse, mutect2, varscan2
- ORAI1 | c.402C>T p.H134= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV100345485; called by muse, mutect2, varscan2
- PAN3 | c.2547A>G p.K849= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as rs1386332666, COSV99145045; called by muse, mutect2, varscan2
- PCDH11X | c.1824C>A p.S608= | Silent (SNP) | VAF 23/86 reads (27%) | catalogued as COSV100014059; called by muse, mutect2, varscan2
- PCDHA8 | c.1776G>A p.A592= | Silent (SNP) | VAF 53/101 reads (52%) | catalogued as rs782636337, COSV65324180; called by muse, mutect2, varscan2
- PCDHB10 | c.2331G>A p.Q777= | Silent (SNP) | VAF 38/99 reads (38%) | catalogued as COSV99504802; called by muse, mutect2, varscan2
- PDCL | c.150C>A p.G50= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99414204; called by muse, mutect2, varscan2
- PDIA2 | c.672C>T p.F224= | Silent (SNP) | VAF 64/125 reads (51%) | catalogued as rs192986117, COSV99250185; called by muse, mutect2, varscan2
- PIK3R4 | c.2445G>A p.Q815= | Silent (SNP) | VAF 106/278 reads (38%) | catalogued as COSV100768547; called by muse, mutect2, varscan2
- PLCB1 | c.36A>G p.Q12= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV100571807; called by muse, mutect2, varscan2
- PPP1R16B | c.996G>A p.L332= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as COSV100239858; called by muse, mutect2, varscan2
- PRAMEF18 | c.804C>T p.N268= | Silent (SNP) | VAF 75/490 reads (15%) | catalogued as rs1400515020; called by muse, mutect2, varscan2
- PRDM8 | c.876C>A p.G292= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100325289; called by muse, mutect2, varscan2
- PRKCQ | c.1113G>A p.L371= | Silent (SNP) | VAF 42/184 reads (23%) | catalogued as COSV54110644, COSV99577564; called by muse, mutect2, varscan2
- PROK2 | c.210A>T p.P70= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV99817035; called by muse, mutect2, varscan2
- PSMD4 | c.306C>T p.G102= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100924686; called by muse, mutect2, varscan2
- PTPRM | c.531G>T p.V177= | Silent (SNP) | VAF 82/166 reads (49%) | catalogued as COSV100159380; called by muse, mutect2, varscan2
- PYHIN1 | c.810T>C p.I270= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as COSV100932393, COSV63722460; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2091T>G p.P697= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as COSV99770373; called by muse, mutect2, varscan2
- RAI1 | c.2223C>T p.A741= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as COSV99884743; called by muse, mutect2, varscan2
- RANBP10 | c.627T>G p.P209= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100449445; called by muse, mutect2, varscan2
- RECK | c.459T>C p.S153= | Silent (SNP) | VAF 57/508 reads (11%) | catalogued as COSV65035774; called by muse, mutect2, varscan2
- RGS20 | c.246C>G p.L82= | Silent (SNP) | VAF 50/187 reads (27%) | catalogued as COSV99392413; called by muse, mutect2, varscan2
- RIMBP2 | c.4C>A p.R2= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV99900140; called by muse, mutect2, varscan2
- RNF38 | c.303C>T p.S101= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as COSV52392775; called by muse, mutect2, varscan2
- RPS6KA2 | c.837G>C p.P279= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV55816279, COSV99691782; called by muse, mutect2, varscan2
- RSPO3 | c.504C>T p.F168= | Silent (SNP) | VAF 71/192 reads (37%) | catalogued as COSV100759628; called by muse, mutect2, varscan2
- SAMD9 | c.2106T>C p.S702= | Silent (SNP) | VAF 56/283 reads (20%) | catalogued as COSV101180331; called by muse, mutect2, varscan2
- SEMA4A | c.987G>A p.Q329= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV100740696; called by muse, mutect2, varscan2
- SLC2A6 | c.132C>G p.A44= | Silent (SNP) | VAF 73/249 reads (29%) | catalogued as rs782207942, COSV100902778, COSV64142330; called by muse, mutect2, varscan2
- SLC44A3 | c.282C>T p.H94= (on ENST00000271227 / NM_001114106.3; = p.H46= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as rs759571114, COSV99598522; called by muse, mutect2, varscan2
- SPANXN3 | c.27T>C p.N9= | Silent (SNP) | VAF 103/261 reads (39%) | catalogued as COSV100980842; called by muse, mutect2, varscan2
- STK11IP | c.2910C>T p.S970= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99823227; called by mutect2, varscan2
- TECRL | c.279C>T p.H93= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101169250; called by muse, mutect2
- TMEM106B | c.375C>T p.Y125= | Silent (SNP) | VAF 36/192 reads (19%) | catalogued as rs758375597, COSV101188863; called by muse, mutect2, varscan2
- TNN | c.1764A>G p.T588= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV99512641; called by muse, mutect2, varscan2
- TRPV4 | c.1731G>A p.V577= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV99924950; called by muse, mutect2, varscan2
- TTC27 | c.201T>C p.D67= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as rs1230431406, COSV100513410; called by muse, mutect2, varscan2
- TUT4 | c.2136G>T p.T712= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV57117293, COSV57120454, COSV99932661; called by muse, mutect2, varscan2
- USP35 | c.2226G>A p.P742= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as rs1046381795, COSV71572678; called by muse, mutect2, varscan2
- YBEY | c.351C>T p.T117= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs1384783557, COSV99388147; called by muse, mutect2, varscan2
- ZBTB16 | c.1683C>A p.L561= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV100251305; called by muse, mutect2, varscan2
- ZCCHC13 | c.285C>T p.G95= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100272566; called by muse, mutect2, varscan2
- ZHX1 | c.60A>T p.P20= | Silent (SNP) | VAF 58/285 reads (20%) | catalogued as COSV99933816; called by muse, mutect2, varscan2
- ZNF202 | c.342C>T p.G114= | Silent (SNP) | VAF 31/183 reads (17%) | catalogued as COSV60246263; called by muse, mutect2, varscan2
- ZNF343 | c.825G>A p.G275= | Silent (SNP) | VAF 38/127 reads (30%) | catalogued as rs1313621212, COSV53853046; called by muse, mutect2, varscan2
- ZNF721 | c.2343C>G p.S781= (on ENST00000338977; = p.S793= on NM_133474.4) | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100167651; called by muse, mutect2, varscan2
- ZPBP | c.33G>T p.R11= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99250247; called by muse, mutect2
- CAPS2 | c.1670-2672A>T | Intron (SNP) | VAF 22/87 reads (25%) | catalogued as COSV100158093; called by muse, varscan2
- CAPS2 | c.1670-2750G>T | Intron (SNP) | VAF 34/161 reads (21%) | catalogued as COSV100158094, COSV60825880; called by muse, varscan2
- EPB41L3 | chr18:5630411 C>G | 5'Flank (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- LINC02145 | n.378T>A | RNA (SNP) | VAF 6/20 reads (30%) | called by muse, varscan2
- MORF4 | n.499G>A | RNA (SNP) | VAF 58/265 reads (22%) | called by muse, mutect2, varscan2
- SNORD115-20 | n.25del | RNA (DEL) | VAF 189/664 reads (28%) | called by mutect2, pindel, varscan2
- SSPOP | n.13453T>A | RNA (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100947843, COSV65130374; called by muse, mutect2, varscan2
- TBC1D22A | c.1015+1165G>T | Intron (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100453525; called by muse, mutect2, varscan2
- ZBTB37 | chr1:173864162 del TTA | 5'Flank (DEL) | VAF 12/91 reads (13%) | called by mutect2, pindel, varscan2
